Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7414, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7414-01A (Primary Tumor).

[page 1 of 3]
- (L) RESECTION LEFT HEMIMANDIBLE, LEFT FLOOR OF MOUTH, LEFT BUCCAL CHEEK:
INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA
OF SALIVARY GLAND. (SEE COMMENT)
Medial deep soft tissue margin of excision involved by tumor;
all other margins of excision free of tumor.
VASCULAR/LYMPHATIC AND PERINEURAL INVASION PRESENT.
METASTATIC SQUAMOUS CELL CARCINOMA IN 1 OF 2 LYMPH NODES.
- (M) ANTERIOR MUCOSAL MARGIN:
Squamous mucosa and soft tissue, no tumor present.
- (N) TONGUE MUCOSAL MARGIN, SUTURE ANTERIOR:
Squamous mucosa and soft tissue, no tumor present.
- (O) POSTERIOR TONGUE MUCOSAL MARGIN:
Squamous mucosa and soft tissue, no tumor present.
- (P) RETROMOLAR TRIGONE:
Soft tissue and skeletal muscle, no tumor present.
- (Q) BUCCAL MUCOSA:
Squamous mucosa and soft tissue, no tumor present.

COMMENT

The tumor measures 7.0 cm in maximum dimension. Its epicenter is in the region of the submandibular salivary gland beneath the skin overlying the mandible. Grossly it involves the mandible and extends from the buccal subcutaneous tissue medially to beneath the oral mucosa. The intervening soft tissue including the submandibular gland and skeletal muscle are involved by tumor. The tumor likely originates in the salivary gland and there is carcinoma in situ present in Wharton's duct and there is no involvement of the epidermis or mucosa. Mucicarmine stains fail to demonstrate intracytoplasmic mucin. Sections of mandible will be reported in a supplemental report following decalcification.

The nodule of squamous cell carcinoma in the subdigastric area measures 1.2 cm in maximum dimension and likely represents an obliterated lymph node. The largest lymph node metastasis completely replaces a lymph node measuring 0.7 cm in maximum dimension. Extranodal extension measuring 0.1 cm is present.

SPECIMEN

- (A) LEFT WHARTON'S DUCT:
(B) SOFT TISSUE SUBMENTAL REGION:
(C) SPINAL ACCESSORY NERVE, CLAMP AWAY FROM MARGIN:
(D) SUPERIOR PART SPINAL ACCESSORY NERVE:
(E) LEFT RADICAL NECK DISSECTION:
(F) SKIN LEFT CHIN:
(G) SKIN, RIGHT CHIN:
(H) LEFT PERIORAL SKIN:
(I) LEFT BUCCAL SKIN:
(J) SKIN, LEFT PAROTID, SUTURE POSTERIOR:
(K) SKIN, LEFT SUBMENTAL, SUTURE ANTERIOR:
(L) RESECTION LEFT HEMIMANDIBLE, LEFT FLOOR OF MOUTH, LEFT BUCCAL CHEEK:
(M) ANTERIOR MUCOSAL MARGIN:
(N) TONGUE MUCOSAL MARGIN, SUTURE ANTERIOR:
(O) POSTERIOR TONGUE MUCOSAL MARGIN:

[page 2 of 3]
DIAGNOSIS :

(L) RESECTION LEFT HEMIMANDIBLE, LEFT FLOOR OF MOUTH, LEFT BUCCAL CHEEK:
COMMENT: Sections of the mandible sent for decalcification demonstrate that the tumor invades into the bone, but the bone margins of resection are free of neoplasm.

DIAGNOSIS

- (A) LEFT WHARTON'S DUCT:
SQUAMOUS CELL CARCINOMA IN SITU, SUPERFICIAL INVASION
CANNOT BE RULED OUT.
- (B) SOFT TISSUE SUBMENTAL REGION:
Fibrous tissue, no tumor present.
- (C) SPINAL ACCESSORY NERVE, CLAMP AWAY FROM MARGIN:
Nerve and soft tissue, no tumor present.
- (D) SUPERIOR PART SPINAL ACCESSORY NERVE:
Peripheral nerve, no tumor present.
- (E) LEFT RADICAL NECK DISSECTION:
METASTATIC SQUAMOUS CELL CARCINOMA IN 9 OF 19 LYMPH NODES
(0 OF 2 SUBDIGASTRIC; 6 OF 7 MIDJUGULAR, 3 OF 5 UPPER
POSTERIOR CERVICAL, 0 OF 5 MIDPOSTERIOR CERVICAL).
(SEE COMMENT)
METASTATIC SQUAMOUS CELL CARCINOMA IN FIBROUS TISSUE OF
THE SUBDIGASTRIC AREA.
- (F) SKIN LEFT CHIN:
Skin, no tumor present.
- (G) SKIN, RIGHT CHIN:
Skin, no tumor present.
- (H) LEFT PERIORAL SKIN:
Skin, no tumor present.
- (I) LEFT BUCCAL SKIN:
Skin, no tumor present.
- (J) SKIN, LEFT PAROTID, SUTURE POSTERIOR:
Skin, no tumor present.
- (K) SKIN, LEFT SUBMENTAL, SUTURE ANTERIOR:
Skin, no tumor present.

[page 3 of 3]
(P) RETROMOLAR TRIGONE:
(Q) BUCCAL MUCOSA:

SNOMED CODES
T-C4100,M-80703

Source: NCI Genomic Data Commons file 16ae363a-c9f1-4399-8758-b753a59b6403 (TCGA-CV-7414.7FE41351-5375-423B-BEC6-6C90058EF85B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).